Somatic mutation profile of tumor specimen MP2PRT-PAPLTV-TMP1-A (aliquot MP2PRT-PAPLTV-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPLTV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (750 days).
Specimen MP2PRT-PAPLTV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b68b2aed-661c-4e1b-87bf-cabc37b69419.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPLTV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPLTV-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/086544c1-7911-4fb3-87ff-c680cd273851

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 98/306 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SETBP1 | c.1765C>T p.R589* | Nonsense Mutation (SNP) | VAF 193/471 reads (41%) | catalogued as rs1568235086; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANO4 | c.1713A>C p.K571N (on ENST00000392977 / NM_001286615.2; = p.K536N on NM_178826.4) | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54609704; called by muse, mutect2
- TENM4 | c.8152C>T p.R2718W | Missense Mutation (SNP) | VAF 209/610 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779399051; called by muse, varscan2
- UNC80 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 111/491 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as rs532329476, COSV99778080; called by muse, mutect2, varscan2
- ASH1L | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 129/336 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TLE4 | c.1720A>T p.T574S | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.317); called by muse, mutect2
- CNGA4 | c.954C>T p.N318= | Silent (SNP) | VAF 114/361 reads (32%) | catalogued as rs375543350, COSV66007053; called by muse, mutect2
- EPHA5 | c.819A>G p.K273= | Silent (SNP) | VAF 20/424 reads (5%) | called by muse, mutect2
- PCDHA12 | c.2253G>A p.S751= | Silent (SNP) | VAF 134/351 reads (38%) | catalogued as COSV56474896; called by muse, varscan2
- SERTAD2 | c.531G>A p.E177= | Silent (SNP) | VAF 47/504 reads (9%) | called by muse, mutect2, varscan2
- TRIO | c.3453G>A p.L1151= | Silent (SNP) | VAF 14/252 reads (6%) | catalogued as COSV100710178; called by muse, mutect2
